Surgical pathology report (de-identified scan), TCGA case TCGA-XK-AAJR, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-XK-AAJR-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

ADDENDUM PRESENT

Patient Name: [REDACTED]
Clinic Number: [REDACTED]
Date of Birth: (Age: Gender: M)
Requested By:

Accession #:
Procedure Date:
Received Date:
Account #:
Report Signed:

Final Diagnosis:

Procedure: Radical prostatectomy.

Histologic type: Prostatic adenocarcinoma, acinar type.

Histologic grade:

Primary pattern: 4, Secondary pattern: 3, Tertiary pattern: 5
Total Gleason Score: 9

Tumor quantitation and location: Bilateral. The predominant tumor is identified in the midportion and base of the left lobe, measuring up to 2.0 cm. Smaller microscopic foci of adenocarcinoma are identified in the left apex, right apex, and right midgland (up to 0.2 cm).

Extraprostatic extension: Present, left base.

Margins: Negative. Tumor very close (less than 1 mm) to inked margin in sections from left mid and left base.

Lymph-vascular invasion: Present, left mid.

Perineural invasion: Present, left mid and left base.

Seminal vesicle invasion: Not identified.

Treatment effect on carcinoma: Not applicable.

Lymph nodes: Eight lymph nodes, negative for malignancy (0/8).

Additional pathologic findings: None.

Ancillary studies: DNA ploidy will be performed and results REPORTED IN AN ADDENDUM.

Pathologic staging: pT3a.

Biorepository sample (if applicable): Tumor present.

Block(s) containing malignancy suitable for additional testing: A9, A11, A13.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS 61.9
JW 3/25/14

Interpreted by:

Report electronically signed out by

Transcribed by:

ADDENDA:

Paraffin embedded tissue (Block A11) was forwarded to report

for DNA Ploidy by DIA testing. This

Source: Prostate, Radical Prostatectomy, block

A11

[page 2 of 4]
[REDACTED]
[REDACTED]
The cancer cells are DNA aneuploid.

DIA ploidy test results have been validated by our laboratory for formalin-fixed, paraffin embedded tissue sections. Analysis was performed using the instrument [REDACTED], which determined DNA ploidy status by comparing the DNA content of tumor cells and control cells (selected by [REDACTED] operator). This test was developed and its performance characteristics determined by [REDACTED]. This test has not been cleared or approved by the U.S. Food and Drug Administration.

Proliferation index Ki-67 (MIB-1) = 4.68%.

Method: Immunohistochemical staining of the Ki-67 antigen in formalin-fixed paraffin-embedded tissue sections has been validated by our laboratory, using the MIB-1 clone and a nonproprietary detection system. All controls show appropriate reactivity. Image collection and analysis is performed using the instrument [REDACTED]. The [REDACTED] renders the percentage of positive staining tumor nuclei (tumor selected by [REDACTED] operator). This test was developed and its performance characteristics determined by [REDACTED]. This test has not been cleared or approved by the U.S. Food and Drug Administration.

Transcribed by

Signed by

Clinical Information:

Prostate cancer.

Specimen(s):

A: Prostate with bilateral lymph nodes

Gross Description:

Performed by [REDACTED] Pathologist's Assistant

A1A2A3A4A5A6A7A8A9A10A11A12A13A14A15A16A17A18A19A20A21A22

Received fresh labeled [REDACTED] and "prostate with bilateral pelvic lymph nodes".

Procedure: Radical prostatectomy with bilateral pelvic lymph node dissection.

Prostate size: Weight: 78 grams; Dimensions: 5.3 x 5 x 4.8 cm; Seminal vesicles: 2 x 1.2 x 0.9 cm.

Gross notes: Grossly evident tumor: Yes, 2 x 2 x 1.5 cm, left base.

Symmetry: Symmetrical.

Gross nodular hyperplasia: Moderate to extensive.

Gross capsular bulge/defect: Yes. The tumor in the left base forms a large bulge in the base of the left capsule.

Inking: left-black, right-blue

Biorepository sample collected: Yes. See block key summary.

Lymph nodes: Multiple pieces of adipose tissue are submitted designated "bilateral pelvic lymph nodes" aggregating to 6 x 4 x 2.5 cm. Within the adipose tissue are multiple fatty lymph nodes.

Block key for specimen A:

- 1) proximal urethral margin
- 2) distal urethral margin
- 3) left apical margin, perpendicular
- 4) right apical margin, perpendicular

[page 3 of 4]
- 5) left bladder neck margin, perpendicular
6) right bladder neck margin, perpendicular
7) left apical prostate
8) right apical prostate
9) left mid prostate
10) right mid prostate
11) left mid prostate
12) right mid prostate
13) left base of prostate
14) right base of prostate
15) left seminal vesicle
16) right seminal vesicle

Additional sections:

- 17) mirror image of tissue corresponding to research
18) one fatty lymph node.
19) one fatty lymph node.
20) four fatty lymph nodes.
21) one fatty lymph node bisected.
22) one fatty lymph node bisected.

*Per TSS dx discrepancy form,
TCBA tumor is Gleason 4+4.*

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by / have not been cleared or approved by the U. S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

PL-001

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

Data Element	Entry Alternatives	Working Instructions
Pathologic Diagnosis Provided on Initial Pathology Report	Adenocarcinoma Gleason 4 + 3 = 7	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Adenocarcinoma Gleason 4 + 4 = 8	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Pathology Gleason score is 7. 4 + 3 = 7	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form. Sample grade is Higher lower at sample Gleason is 4 + 4 = 8 -
Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Date

Source: NCI Genomic Data Commons file 5d1642ea-24f5-4824-9e72-cdf5cf6a8509 (TCGA-XK-AAJR.2FB129E0-B651-4F2F-96DA-B2CCECD4F432.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).